CCDI case PBCKLC — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Ovary.
https://portal.gdc.cancer.gov/cases/8505dda0-9d45-48e8-a738-dfad74421fad

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Small cell carcinoma, NOS: ICD-O-3 morphology code: 8041/3; Tissue or organ of origin: Ovary; Age at diagnosis: 17.0 years (6,227 days).

Biospecimens (3 samples)
- Sample 0DUB69: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DUB88: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DUB9M: Tissue type: Tumor; Specimen type: Solid Tissue.
